Somatic mutation profile of tumor specimen TCGA-85-7710-01A (aliquot TCGA-85-7710-01A-11D-2122-08) from TCGA case TCGA-85-7710, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.7 years (21,790 days).
Specimen TCGA-85-7710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8e088c9-f270-479c-8636-c9717425734d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-7710-10A (Blood Derived Normal), aliquot TCGA-85-7710-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eafefbc-4cf2-4fcc-a02f-a39c2e55ebc7

The open-access MAF lists 206 somatic variants for this specimen: 157 protein-altering or splice-affecting, 42 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 42, Nonsense Mutation 8, Frame Shift Del 6, Intron 4, Splice Site 2, Splice Region 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 24/43 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.4217G>A p.S1406N | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100588707; called by muse, mutect2, varscan2
- ACTG1 | c.50G>A p.C17Y | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100111944, COSV59510454; called by muse, varscan2
- ADAM2 | c.991T>A p.C331S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99697373; called by muse, mutect2, varscan2
- ADAMTS16 | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as COSV99941371; called by muse, mutect2
- ADPRH | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV100813318; called by muse, mutect2, varscan2
- AKT1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs775892860, COSV100838135, COSV62575169; called by muse, mutect2, varscan2
- APEX2 | c.959A>T p.Q320L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100238363; called by muse, mutect2, varscan2
- APOO | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV101004899; called by muse, mutect2, varscan2
- ARAF | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); catalogued as COSV99283212; called by muse, mutect2, varscan2
- ATP6AP2 | c.109A>C p.I37L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV101011510, COSV101011540; called by muse, mutect2, varscan2
- ATP8A2 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745650033, COSV54942586; called by muse, mutect2, varscan2
- C12orf40 | c.384G>A p.Q128= | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100210127, COSV61137666; called by muse, mutect2, varscan2
- C1R | c.557A>T p.Y186F (on ENST00000536053 / NM_001354346.2; = p.Y172F on NM_001733.7) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99864713; called by muse, mutect2, varscan2
- CACNA1E | c.6247C>G p.R2083G (on ENST00000367573 / NM_001205293.3; = p.R2040G on NM_000721.4) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100702838, COSV62389153; called by muse, mutect2, varscan2
- CADM3 | c.1027C>A p.L343M (on ENST00000368125 / NM_001127173.3; = p.L377M on NM_021189.5) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); catalogued as COSV100929907; called by muse, mutect2, varscan2
- CAMK2B | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99323090; called by muse, mutect2, varscan2
- CARS2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99959660; called by muse, mutect2, varscan2
- CCDC171 | c.2481G>T p.W827C | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52635396, COSV99900902; called by muse, mutect2, varscan2
- CCDC88B | c.2708A>T p.Q903L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100105460; called by muse, mutect2, varscan2
- CD320 | c.618G>C p.E206D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs749530258, COSV100035818; called by muse, mutect2, varscan2
- CDH4 | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100848980; called by muse, mutect2, varscan2
- CDH9 | c.1285C>G p.R429G | Missense Mutation (SNP) | VAF 70/122 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV99145164, COSV99150623; called by muse, mutect2, varscan2
- CEP170 | c.4021G>T p.A1341S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV100317146; called by muse, mutect2, varscan2
- CHRM2 | c.328T>C p.S110P | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100281358; called by muse, mutect2, varscan2
- CNKSR2 | c.1300T>A p.Y434N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as COSV99668657; called by muse, mutect2, varscan2
- COL4A6 | c.4091G>A p.G1364D | Missense Mutation (SNP) | VAF 87/164 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564196; called by muse, mutect2, varscan2
- COL6A3 | c.6127C>T p.R2043C | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1001689383, COSV99798518; called by muse, mutect2, varscan2
- CRISPLD1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771493194, COSV100082046; called by muse, mutect2, varscan2
- CYB5RL | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99839012; called by muse, mutect2, varscan2
- CYP19A1 | c.738G>C p.K246N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV99547742; called by muse, mutect2
- CYP46A1 | c.653T>C p.M218T | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs766557064, COSV99952634; called by muse, mutect2, varscan2
- CYP4F12 | c.976A>G p.M326V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100215878; called by muse, mutect2, varscan2
- DMD | c.3541C>T p.L1181F | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763213050, COSV100819853; called by muse, mutect2, varscan2
- DMD | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM150623, COSV99922694; called by muse, mutect2, varscan2
- DNAH5 | c.5724C>G p.I1908M | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99450218; called by muse, mutect2, varscan2
- DSP | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101131295; called by muse, mutect2, varscan2
- EFNA1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV100310365; called by muse, mutect2, varscan2
- ELAPOR2 | c.1825C>T p.L609F (on ENST00000450689 / NM_001142749.3; = p.L442F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99788837; called by muse, mutect2, varscan2
- F13B | c.515T>A p.V172E | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100803299; called by muse, mutect2, varscan2
- FAM47B | c.1595G>T p.R532L | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100264356, COSV61452814; called by muse, mutect2, varscan2
- FBN3 | c.3035C>G p.A1012G | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV99561013, COSV99561587; called by muse, mutect2, varscan2
- FGD5 | c.3977G>A p.R1326H | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs776541198, COSV99548170; called by muse, mutect2
- GABRG2 | c.853C>G p.L285V (on ENST00000361925 / NM_001375343.1; = p.L245V on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.992); catalogued as COSV100729711; called by muse, mutect2, varscan2
- GBP1 | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 161/303 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100976264; called by muse, varscan2
- GNPNAT1 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99369539; called by muse, mutect2, varscan2
- GPRASP1 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 63/129 reads (49%) | catalogued as COSV100851000; called by muse, mutect2, varscan2
- GRHL3 | c.293C>T p.T98M (on ENST00000350501 / NM_198174.3; = p.T103M on NM_021180.3) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs372226155; called by muse, mutect2, varscan2
- GRIPAP1 | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100904295; called by muse, mutect2, varscan2
- H3C4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV61911648, COSV61911890; called by muse, mutect2, varscan2
- HDAC6 | c.2791G>A p.G931R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as rs1557030778, COSV100490880; called by muse, mutect2, varscan2
- HOPX | c.176G>T p.R59L (on ENST00000317745; = p.R77L on NM_032495.6) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV100497044; called by muse, mutect2, varscan2
- IGLV3-25 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs773935699; called by muse, mutect2, varscan2
- IQCE | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100383423; called by muse, mutect2, varscan2
- KIAA1109 | c.1050G>A p.Q350= | Splice Region (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99164154; called by muse, mutect2, varscan2
- KLHL4 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.138); catalogued as COSV100909633, COSV64139377; called by muse, mutect2
- KRT86 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99524967; called by muse, mutect2, varscan2
- LGR4 | c.2735A>T p.E912V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as COSV100156595; called by muse, mutect2, varscan2
- LMTK3 | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99540547; called by muse, mutect2, varscan2
- LRFN5 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV99984043; called by muse, mutect2, varscan2
- LRP1B | c.5915A>T p.H1972L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV67187765; called by muse, mutect2, varscan2
- LRP1B | c.5914C>A p.H1972N | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV101257592, COSV67243114; called by muse, mutect2, varscan2
- MAGEC2 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99909620; called by muse, mutect2, varscan2
- MAPK4 | c.1182G>C p.Q394H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101245527; called by muse, mutect2
- MED12 | c.5966G>A p.R1989H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1569482448, COSV61360023; called by muse, mutect2, varscan2
- MGAM | c.4227G>C p.E1409D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV101527450, COSV101527514; called by muse, mutect2, varscan2
- MORC1 | c.1195G>T p.G399* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV99226280; called by muse, mutect2, varscan2
- MROH8 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.149); catalogued as COSV99457349; called by muse, varscan2
- MRPL42 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as rs1253665802, COSV62357539; called by muse, mutect2, varscan2
- NAA15 | c.2057-1G>A p.X686_splice | Splice Site (SNP) | VAF 17/49 reads (35%) | catalogued as COSV56718356, COSV99649604; called by muse, mutect2, varscan2
- NF2 | c.834G>C p.K278N | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100098489; called by muse, mutect2, varscan2
- NLGN3 | c.1384G>T p.A462S (on ENST00000358741 / NM_181303.2; = p.A442S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV100704795; called by muse, mutect2, varscan2
- NLRP13 | c.2209A>T p.K737* | Nonsense Mutation (SNP) | VAF 43/106 reads (41%) | catalogued as COSV100738275; called by muse, mutect2, varscan2
- NPC1 | c.3067G>T p.V1023F | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99341375; called by muse, mutect2
- OR10K2 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs111878656, COSV59220924; called by muse, mutect2, varscan2
- OR4K15 | c.437G>T p.R146L (on ENST00000305051; = p.R122L on NM_001005486.1) | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100521044, COSV59303142; called by muse, mutect2, varscan2
- OR4M1 | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV100271237; called by muse, mutect2, varscan2
- OR52A5 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV100263463; called by muse, mutect2, varscan2
- OR5H14 | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 244/388 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101454197; called by muse, mutect2, varscan2
- P2RY10 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99409149; called by muse, mutect2, varscan2
- PCDH1 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs1228012689, COSV99746304; called by muse, mutect2, varscan2
- PCDH11X | c.1967G>T p.S656I | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV100008015, COSV100011954; called by muse, mutect2, varscan2
- PCDH11X | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV100011957, COSV100014747; called by muse, mutect2, varscan2
- PDE11A | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs770158287, COSV99612580; called by muse, mutect2, varscan2
- PEG3 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1274774138, COSV99689113; called by muse, mutect2, varscan2
- PFKFB1 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 51/96 reads (53%) | PolyPhen possibly damaging (0.612); catalogued as COSV100895721; called by muse, mutect2, varscan2
- PKD1L2 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as COSV100216636; called by muse, mutect2, varscan2
- PLCH1 | c.997G>T p.A333S (on ENST00000340059 / NM_001130960.2; = p.A345S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV100396972; called by muse, mutect2, varscan2
- PLXNB1 | c.6233A>G p.Y2078C | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV99602885; called by muse, varscan2
- POTEE | c.2332A>T p.N778Y | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100388001; called by muse, mutect2, varscan2
- PRDM9 | c.2156C>A p.P719H | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99690511; called by muse, varscan2
- PTGS2 | c.829G>T p.V277F | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV100821764; called by muse, mutect2, varscan2
- QSER1 | c.3735C>G p.S1245R (on ENST00000399302; = p.S1374R on NM_001076786.3) | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs371032912, COSV101234856, COSV67900743; called by muse, mutect2, varscan2
- RAB28 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 40/131 reads (31%) | catalogued as COSV99986268; called by muse, mutect2, varscan2
- RABGAP1L | c.1522A>T p.K508* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99270545; called by muse, mutect2, varscan2
- RAC1 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100641015, COSV61823555; called by muse, mutect2, varscan2
- RB1 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 31/51 reads (61%) | catalogued as CM961223, COSV99924935; called by muse, mutect2, varscan2
- REC8 | c.941T>G p.I314S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100269060; called by muse, mutect2, varscan2
- RGS6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59600253; called by muse, mutect2, varscan2
- RIN2 | c.2384C>T p.S795F (on ENST00000255006 / NM_001242581.1; = p.S746F on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV54791139, COSV99657208, COSV99657631; called by muse, mutect2, varscan2
- ROBO3 | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV101185058; called by muse, mutect2, varscan2
- RYR1 | c.7108G>C p.G2370R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100615819; called by muse, mutect2, varscan2
- SAMHD1 | c.625G>T p.G209C | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM093959, COSV99484082; called by muse, varscan2
- SCP2D1 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53859022, COSV99602065; called by muse, mutect2, varscan2
- SERPINA6 | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV100448306; called by muse, mutect2, varscan2
- SERPINE3 | c.1243C>T p.H415Y | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV100247089; called by muse, mutect2, varscan2
- SHANK2 | c.4017G>A p.M1339I | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1443650011, COSV53616693; called by muse, mutect2, varscan2
- SHOC1 | c.3418C>T p.Q1140* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100597661; called by muse, mutect2, varscan2
- SLC25A34 | c.670A>G p.M224V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs368494661; called by muse, mutect2, varscan2
- SLC2A9 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99304701; called by muse, mutect2, varscan2
- SLC35A2 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as CM149400, COSV99504322; called by muse, mutect2, varscan2
- SLC45A4 | c.2399T>A p.I800N (on ENST00000517878 / NM_001286646.2; = p.F747I on NM_001080431.2) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1248963620, COSV50186823; called by muse, varscan2
- SLC6A3 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99548411; called by muse, mutect2, varscan2
- SLITRK2 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100157802; called by muse, mutect2, varscan2
- SLITRK2 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100157805; called by muse, mutect2, varscan2
- SPTA1 | c.1679T>C p.L560P | Missense Mutation (SNP) | VAF 127/196 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100935030; called by muse, mutect2, varscan2
- SQLE | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV99772352; called by muse, mutect2, varscan2
- STAB1 | c.6611-2A>G p.X2204_splice | Splice Site (SNP) | VAF 29/55 reads (53%) | catalogued as COSV100195053; called by muse, mutect2, varscan2
- SYT15 | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100970446; called by muse, mutect2, varscan2
- SYTL4 | c.1966G>C p.G656R | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99342937; called by muse, mutect2, varscan2
- TAF1C | c.2030A>T p.Q677L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV100499612; called by muse, mutect2, varscan2
- TALDO1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs140985565; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM3 | c.6265G>A p.E2089K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs865783014, COSV101305149; called by muse, mutect2, varscan2
- TENT5D | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100382770; called by muse, mutect2, varscan2
- TJP1 | c.2833G>T p.V945F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV100632746; called by muse, mutect2, varscan2
- TMEM139 | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100131008; called by muse, mutect2, varscan2
- TMEM256 | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV100192812; called by muse, mutect2, varscan2
- TMEM256 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100192814, COSV56658824; called by muse, mutect2, varscan2
- TOPORS | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV100598306; called by muse, mutect2, varscan2
- TRPC3 | c.313C>A p.R105S (on ENST00000379645 / NM_001366479.2; = p.R32S on NM_003305.2) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.173); catalogued as COSV53373055, COSV99312707; called by muse, mutect2, varscan2
- TTN | c.26929G>T p.V8977F (on ENST00000591111; = p.V8050F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV100615002; called by muse, mutect2, varscan2
- USF3 | c.4841C>G p.S1614* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100325344; called by muse, mutect2, varscan2
- USF3 | c.4502C>G p.S1501C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1428863386, COSV100325345, COSV100325677; called by muse, mutect2, varscan2
- USH2A | c.9852del p.R3285Gfs*16 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as COSV100232962; called by mutect2, pindel, varscan2
- USH2A | c.8551A>C p.N2851H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100235609, COSV56453437; called by muse, mutect2
- VPS13D | c.5239C>T p.R1747W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs534368672, COSV50649431; called by muse, mutect2, varscan2
- WDR46 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.706); catalogued as COSV101004792; called by muse, mutect2, varscan2
- WDR7 | c.3889A>T p.T1297S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99589541; called by muse, mutect2, varscan2
- XDH | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101052207; called by muse, mutect2, varscan2
- XRN1 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99378074; called by muse, mutect2, varscan2
- XYLT1 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99761939; called by muse, mutect2
- ZC3H12B | c.2384C>A p.T795N | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100161767; called by muse, mutect2, varscan2
- ZFHX4 | c.5158C>A p.P1720T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99263165; called by muse, mutect2, varscan2
- ZFYVE9 | c.2615T>A p.L872Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); catalogued as COSV99820068; called by muse, mutect2, varscan2
- ZNF485 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as COSV62425921; called by muse, mutect2, varscan2
- ZNF536 | c.448C>A p.R150S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834794, COSV100835275; called by muse, mutect2, varscan2
- ZNF592 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100245890; called by muse, varscan2
- ZNF683 | c.1048T>C p.F350L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100853715; called by muse, mutect2, varscan2
- ZNF80 | c.500del p.G167Efs*10 | Frame Shift Del (DEL) | VAF 40/158 reads (25%) | catalogued as COSV100352072; called by mutect2, pindel, varscan2
- CMYA5 | c.11135del p.P3712Lfs*18 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- CSF2RB | c.2109_2112del p.E703Dfs*27 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | called by mutect2, pindel, varscan2
- KCNG4 | c.452del p.G151Afs*16 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.824C>A p.T275K | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.19); called by muse, varscan2
- MAGEB6B | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 108/224 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUTM2G | c.663del p.R222Gfs*30 | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by mutect2, pindel, varscan2
- TLE2 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2
- ADAMTS3 | c.2310G>A p.E770= | Silent (SNP) | VAF 75/193 reads (39%) | catalogued as COSV99711159; called by muse, mutect2, varscan2
- ARNTL | c.741C>T p.F247= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV100724735, COSV62985136; called by muse, mutect2, varscan2
- ATRX | c.4441C>A p.R1481= | Silent (SNP) | VAF 144/314 reads (46%) | catalogued as COSV100970390, COSV64880586; called by muse, varscan2
- B3GNT3 | c.312G>A p.A104= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs144986276; called by muse, mutect2, varscan2
- C11orf87 | c.186G>A p.L62= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100535811; called by muse, mutect2
- CCDC113 | c.840G>A p.L280= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV99540707, COSV99540975; called by muse, mutect2, varscan2
- CD5L | c.138C>G p.G46= | Silent (SNP) | VAF 122/199 reads (61%) | catalogued as COSV100941023, COSV100941055; called by muse, mutect2, varscan2
- CLDND1 | c.553C>T p.L185= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs779474164, COSV100360739; called by mutect2, varscan2
- CPNE2 | c.112C>A p.R38= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV51964341, COSV99321420; called by muse, mutect2, varscan2
- DLK1 | c.780C>T p.S260= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs1030350283, COSV100375238; called by muse, mutect2, varscan2
- DMXL2 | c.6639G>A p.A2213= | Silent (SNP) | VAF 57/142 reads (40%) | catalogued as rs185024518, COSV51845622; called by muse, mutect2, varscan2
- DSPP | c.876T>C p.D292= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1291727576, COSV99217427; called by muse, mutect2, varscan2
- EIF5 | c.294C>T p.L98= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs1400097346, COSV99384845; called by muse, mutect2, varscan2
- EPHB3 | c.663C>T p.L221= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100383093; called by muse, mutect2, varscan2
- ESF1 | c.84G>A p.K28= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs888967158, COSV99176375; called by muse, mutect2, varscan2
- FOXA3 | c.270C>T p.S90= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs745781153, COSV100141401; called by muse, varscan2
- FRMD5 | c.282G>A p.V94= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as COSV68721027; called by muse, mutect2, varscan2
- FRMPD3 | c.525C>A p.L175= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99346384; called by muse, mutect2, varscan2
- GAPT | c.198C>T p.I66= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100576292; called by muse, mutect2, varscan2
- GPR179 | c.3297G>A p.R1099= (on ENST00000621958; = p.R1098= on NM_001004334.4) | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1307804914; called by muse, mutect2, varscan2
- IQCE | c.945G>C p.L315= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100383420; called by muse, mutect2, varscan2
- KALRN | c.2451G>A p.R817= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV53782424, COSV99564738; called by muse, mutect2, varscan2
- KRT85 | c.240C>T p.F80= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs778706364, COSV57736391; called by mutect2, varscan2
- MYOM1 | c.4956T>C p.Y1652= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs760618494, COSV99866828; called by muse, mutect2, varscan2
- NHS | c.3765G>A p.R1255= | Silent (SNP) | VAF 78/155 reads (50%) | catalogued as COSV101196625; called by muse, mutect2, varscan2
- OR1C1 | c.141G>C p.A47= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV101376230, COSV68715440, COSV68715730; called by muse, mutect2, varscan2
- OR4D1 | c.498G>A p.L166= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV99274167; called by muse, mutect2, varscan2
- OR5M11 | c.120A>G p.L40= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV101602046; called by muse, mutect2, varscan2
- PHKB | c.3178C>T p.L1060= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV100067250; called by muse, mutect2, varscan2
- POF1B | c.144G>C p.V48= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV99426759; called by muse, mutect2, varscan2
- REC8 | c.102G>C p.L34= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100269056, COSV61018735; called by muse, varscan2
- ST7 | c.1182G>A p.G394= (on ENST00000265437 / NM_021908.3; = p.G371= on NM_018412.4) | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs767855046, COSV99622002; called by muse, mutect2, varscan2
- SV2C | c.375A>G p.S125= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs750688144, COSV100456270; called by muse, mutect2, varscan2
- TAS2R31 | c.693G>A p.V231= | Silent (SNP) | VAF 84/214 reads (39%) | catalogued as COSV66830029; called by muse, varscan2
- TCOF1 | c.4398C>G p.T1466= (on ENST00000377797 / NM_001135243.1; = p.T1389= on NM_000356.4) | Silent (SNP) | VAF 44/64 reads (69%) | catalogued as COSV99153821; called by muse, mutect2, varscan2
- TNN | c.1350C>G p.V450= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99512051; called by muse, mutect2, varscan2
- TNRC6C | c.4473C>A p.P1491= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100050038; called by muse, mutect2, varscan2
- TRBV4-2 | c.228C>T p.N76= | Silent (SNP) | VAF 52/334 reads (16%) | called by muse, mutect2, varscan2
- UNC13C | c.5412G>A p.L1804= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99517903; called by muse, mutect2, varscan2
- USF3 | c.5484C>G p.L1828= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as COSV100325343, COSV57074916; called by muse, mutect2, varscan2
- ZC3H12B | c.2385C>A p.T795= | Silent (SNP) | VAF 42/85 reads (49%) | catalogued as COSV100161770; called by muse, mutect2, varscan2
- ZFHX4 | c.7065C>T p.A2355= | Silent (SNP) | VAF 42/143 reads (29%) | catalogued as COSV99263166; called by muse, mutect2, varscan2
- ACE | c.1922-268A>G | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99327060; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505824 A>G | 5'Flank (SNP) | VAF 30/98 reads (31%) | catalogued as rs558535854; called by muse, mutect2, varscan2
- CACNA1C | c.1391-2447T>A | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100219244; called by muse, mutect2, varscan2
- GRIA4 | c.1269+1365C>T | Intron (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99231775; called by muse, mutect2, varscan2
- NUDCD3 | c.509+16847C>T | Intron (SNP) | VAF 63/207 reads (30%) | called by muse, mutect2, varscan2
- PCDH11X | n.559C>G | RNA (SNP) | VAF 43/97 reads (44%) | called by muse, mutect2, varscan2
- SSX9P | n.21A>C | RNA (SNP) | VAF 159/332 reads (48%) | called by muse, varscan2
